CCDI case PBCFJK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/e863092f-00c0-4c6a-93d8-4a1c6dc21fc5

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Conjunctiva; Age at diagnosis: 3.6 years (1,323 days).

Biospecimens (3 samples)
- Sample 0DRB5F: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRB5Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRB5T: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
